Somatic mutation profile of tumor specimen 0DGOA8 from CCDI case PBBTNE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.5 years (3,465 days).
Specimen 0DGOA8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08d59a80-6047-447e-93f0-09509b0a9781.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGOBA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f07d1561-dbc3-4265-bf24-3c234a84f59e

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, 3'UTR 3, Intron 2, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 326/1509 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDH9 | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 324/1535 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as COSV50449579, COSV99144167; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.3013C>T p.R1005W | Missense Mutation (SNP) | VAF 109/461 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs769206349; called by muse, mutect2, varscan2
- TMEM54 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 268/585 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV61276325; called by muse, mutect2, varscan2
- VPS13A | c.4129A>G p.T1377A | Missense Mutation (SNP) | VAF 233/1027 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); catalogued as rs760948401; called by muse, mutect2, varscan2
- VPS26B | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 232/750 reads (31%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.548); catalogued as rs752690816; called by muse, mutect2, varscan2
- ANKRD40CL | c.156C>G p.F52L (on ENST00000643007; = p.F24L on NM_001358683.3) | Missense Mutation (SNP) | VAF 269/2270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HKDC1 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 533/1134 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KRT34 | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 1104/2885 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SCN11A | c.4982A>G p.K1661R | Missense Mutation (SNP) | VAF 270/1329 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- UMPS | c.124_125dup p.I43Afs*9 | Frame Shift Ins (INS) | VAF 246/1132 reads (22%) | called by mutect2, varscan2
- XYLB | c.56A>C p.Q19P | Missense Mutation (SNP) | VAF 141/717 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZMYM3 | c.3582_3584dup p.L1194_W1195insC | In Frame Ins (INS) | VAF 412/454 reads (91%) | called by mutect2, varscan2
- AP1AR | c.102A>G p.T34= | Silent (SNP) | VAF 136/1232 reads (11%) | catalogued as rs1368967719; called by muse, mutect2, varscan2
- BACH1 | c.1086T>A p.G362= | Silent (SNP) | VAF 308/1560 reads (20%) | called by muse, mutect2, varscan2
- CSMD3 | c.7404C>G p.V2468= (on ENST00000297405 / NM_001363185.1; = p.V2364= on NM_052900.3) | Silent (SNP) | VAF 498/1805 reads (28%) | catalogued as COSV99845448; called by muse, mutect2, varscan2
- LRRC61 | c.687G>A p.E229= | Silent (SNP) | VAF 65/372 reads (17%) | catalogued as rs1223016512; called by muse, mutect2, varscan2
- TARS2 | c.1374C>T p.D458= | Silent (SNP) | VAF 241/1082 reads (22%) | catalogued as rs762924252, COSV64695231; called by muse, mutect2, varscan2
- HS6ST1 | c.*91G>T | 3'UTR (SNP) | VAF 25/46 reads (54%) | called by mutect2, varscan2
- MAPK4 | c.*14G>T | 3'UTR (SNP) | VAF 75/364 reads (21%) | called by muse, mutect2, varscan2
- NAV2 | c.2977-48C>T | Intron (SNP) | VAF 149/426 reads (35%) | called by muse, mutect2, varscan2
- PACS1 | c.2429+16G>A | Intron (SNP) | VAF 123/441 reads (28%) | catalogued as rs771886262; called by muse, mutect2, varscan2
- UBE2M | c.*18C>A | 3'UTR (SNP) | VAF 93/400 reads (23%) | catalogued as rs775028303; called by muse, mutect2, varscan2
